Somatic mutation profile of tumor specimen 0DQ810 from CCDI case PBCEUG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 6.5 years (2,380 days).
Specimen 0DQ810: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 146e8f0a-6f55-44af-9354-eb70bc04d08d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7WH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01cb88e0-60cd-4a56-a4ae-afd06683ee19

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 3, 5'Flank 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSL | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1272438892, COSV66964961; called by muse, mutect2, varscan2
- BAIAP2 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 74/530 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1242252565; called by muse, mutect2, varscan2
- BCAS1 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 110/445 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65086426; called by muse, mutect2, varscan2
- CYHR1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 109/435 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs1416037923, COSV101446303; called by muse, mutect2, varscan2
- LILRA1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs771954481, COSV99251925; called by muse, mutect2, varscan2
- MUCL3 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 140/828 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1161452074; called by muse, mutect2, varscan2
- NDN | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 93/364 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59358876; called by muse, mutect2, varscan2
- PTK2B | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 156/323 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1239273029, COSV57751086; called by muse, mutect2, varscan2
- SOBP | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 58/409 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs1351570525; called by muse, mutect2, varscan2
- TPR | c.6331C>T p.R2111C | Missense Mutation (SNP) | VAF 141/339 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66602758; called by muse, mutect2, varscan2
- WDR81 | c.5134G>A p.V1712M (on ENST00000409644 / NM_001163809.2; = p.V661M on NM_152348.4) | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs753925058; called by muse, mutect2
- DDX11 | c.848A>G p.D283G | Missense Mutation (SNP) | VAF 124/624 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- DHX29 | c.276C>G p.N92K | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FCRLA | c.467T>G p.V156G (on ENST00000367959; = p.V133G on NM_032738.4) | Missense Mutation (SNP) | VAF 99/464 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- SKIDA1 | c.29A>G p.E10G | Missense Mutation (SNP) | VAF 116/467 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SNRNP200 | c.4463T>G p.V1488G | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SNX21 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 132/535 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STK31 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 85/509 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UNC13B | c.3770C>T p.S1257L | Missense Mutation (SNP) | VAF 116/493 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CLEC4M | c.351C>T p.T117= | Silent (SNP) | VAF 285/687 reads (41%) | called by muse, mutect2, varscan2
- ARNT2 | c.*57C>A | 3'UTR (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- NEBL | c.2055+66C>A | Intron (SNP) | VAF 47/149 reads (32%) | catalogued as rs906130401; called by muse, mutect2, varscan2
- PLCG2 | c.765+91T>C | Intron (SNP) | VAF 27/72 reads (38%) | catalogued as rs142833782; called by muse, mutect2, varscan2
- SPATA6L | c.430-813G>T | Intron (SNP) | VAF 40/198 reads (20%) | called by muse, mutect2, varscan2
- ZNF22 | chr10:45000783 G>C | 5'Flank (SNP) | VAF 125/513 reads (24%) | called by muse, mutect2, varscan2
